Surgical pathology report (de-identified scan), TCGA case TCGA-61-2111, project TCGA-OV (Ovarian Serous Cystadenocarcinoma), tissue source site University of Pittsburgh, specimen TCGA-61-2111-01A (Primary Tumor).

FINAL DIAGNOSIS:

FINAL DIAGNOSIS:

A) OMENTUM WITH METASTATIC POORLY DIFFERENTIATED ADENOCARCINOMA

METASTATIC POORLY DIFFERENTIATED SEROUS ADENOCARCINOMA WITH PSAMMOMA BODIES (CLINICALLY FROM UTERINE SEROSA) (SEE NOTE)

UTERUS WITH BOTH ADNEXA, 180 GRAMS:

- METASTATIC ADENOCARCINOMA INVOLVING CERVICAL STROMA
- CHRONIC CYSTIC CERVICITIS WITH SQUAMOUS METAPLASIA
- PAPILLARY SEROUS ADENOCARCINOMA OF ENDOMETRIUM INVOLVING 60% OF SURFACE WITH 20% INVASION INTO MYOMETRIUM ("C4") (SEE NOTE)
- ENDOMETRIAL POLYP INVOLVED WITH TUMOR
- ADENOMYOSIS
- MULTIPLE LEIOMYOMAS, UP TO 6.0 CM.
- LEFT OVARY WITH PAPILLARY SEROUS ADENOCARCINOMA
- LEFT FALLOPIAN TUBE, NO TUMOR SEEN
- RIGHT FALLOPIAN TUBE, NO TUMOR SEEN
- RIGHT OVARY WITH SEROSAL ADHESIONS AND EPITHELIUM INCLUSIONS, NO TUMOR SEEN
- D) THREE (3) LEFT EXTERNAL ILIAC LYMPH NODES, FREE OF TUMOR
- E) ONE (1) LEFT OBTURATOR LYMPH NODE, FREE OF TUMOR
- F) TWO (2) RIGHT EXTERNAL ILIAC LYMPH NODES, FREE OF TUMOR
- G) THREE (3) RIGHT OBTURATOR LYMPH NODES, FREE OF TUMOR
- H) FIBROVASCULAR FATTY TISSUE, NO LYMPH NODES OR TUMOR SEEN

NOTE: This endometrial tumor represents a FIGO stage 3A serous adenocarcinoma. The peritoneal cytology is positive for malignancy.

Source: NCI Genomic Data Commons file 222694d4-c205-46fd-ab31-877c9ad13be7 (TCGA-61-2111.351930BC-AC4D-468E-9FE2-BA6F16C01444.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).